Somatic mutation profile of tumor specimen MMRF_2739_1_BM_CD138pos (aliquot MMRF_2739_1_BM_CD138pos_T1_KHS5U_L14890) from MMRF case MMRF_2739, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.2 years (15,776 days).
Specimen MMRF_2739_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0848f075-09a9-49b1-9387-0fcc92046391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2739_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2739_1_PB_WBC_C3_KHS5U_L14891; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d8c271-c2cd-47b4-8791-38b258056222

The open-access MAF lists 176 somatic variants for this specimen: 38 protein-altering or splice-affecting, 20 silent, 118 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 73, Missense Mutation 33, Silent 20, Intron 18, 5'UTR 14, 5'Flank 6, 3'Flank 4, Nonsense Mutation 3, RNA 3, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS7 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs778559290, COSV101182989, COSV66306530; called by muse, mutect2, varscan2
- ADGRL4 | c.1366C>G p.Q456E | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66059936; called by muse, mutect2, varscan2
- AP2M1 | c.430-7C>T | Splice Region (SNP) | VAF 87/179 reads (49%) | catalogued as COSV53050120; called by muse, mutect2, varscan2
- ATP6V0A4 | c.728G>C p.R243P | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377068937; called by muse, mutect2, varscan2
- C11orf80 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58993251; called by muse, mutect2, varscan2
- COL4A1 | c.3059G>A p.G1020E | Missense Mutation (SNP) | VAF 70/76 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101010918, COSV65428053; called by muse, mutect2, varscan2
- DDX50 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 118/122 reads (97%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs749171669, COSV65291865; called by muse, varscan2
- DMD | c.11018G>A p.R3673K | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1795743; called by muse, mutect2, varscan2
- FAM189A1 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs1216377010; called by muse, mutect2, varscan2
- INPP4A | c.2698G>A p.D900N (on ENST00000074304 / NM_001134224.1; = p.D861N on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99304620; called by muse, varscan2
- MAP1A | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772092794; called by muse, mutect2, varscan2
- PLA2R1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1369328710, COSV51788570; called by muse, mutect2, varscan2
- RPS6KA2 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV55819377; called by muse, mutect2, varscan2
- SLX4 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs774244807, COSV53569819; called by muse, mutect2
- TRAPPC8 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.137); catalogued as COSV51972511; called by muse, mutect2, varscan2
- TTN | c.2950G>C p.E984Q (on ENST00000591111; = p.E938Q on NM_003319.4) | Missense Mutation (SNP) | VAF 75/157 reads (48%) | PolyPhen probably damaging (0.998); catalogued as COSV100604001, COSV60116882; called by muse, mutect2, varscan2
- ZNF121 | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 6/123 reads (5%) | catalogued as COSV57552057; called by muse, mutect2
- ZNF493 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs777016756; called by muse, mutect2
- ABCC11 | c.1455G>T p.Q485H | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- AL662899.2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2
- CEBPE | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- CELSR2 | c.6424G>T p.E2142* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- CFAP97D1 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CYP2A6 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.384); called by muse, varscan2
- FAM221B | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- GPR37 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, mutect2
- INTS1 | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KARS1 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIRREL2 | c.1153C>G p.R385G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT28 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PLA2G4F | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR36 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- SLC38A2 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC2 | c.2683G>C p.E895Q | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SORCS1 | c.2947T>A p.F983I | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYPL2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- THUMPD2 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- USH2A | c.3811+1G>T p.X1271_splice | Splice Site (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- AKIRIN1 | c.21G>A p.L7= | Silent (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
- CROCC | c.1785G>A p.R595= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- DBP | c.333C>T p.F111= | Silent (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- DND1 | c.1061G>A p.*354= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, varscan2
- FBXO4 | c.585G>A p.L195= | Silent (SNP) | VAF 82/170 reads (48%) | called by muse, varscan2
- HEY1 | c.303G>A p.L101= | Silent (SNP) | VAF 47/122 reads (39%) | called by muse, mutect2, varscan2
- ITPKB | c.24C>G p.L8= | Silent (SNP) | VAF 49/124 reads (40%) | called by muse, mutect2, varscan2
- LONRF1 | c.24G>A p.R8= | Silent (SNP) | VAF 16/22 reads (73%) | called by muse, mutect2, varscan2
- NAA15 | c.441G>A p.Q147= | Silent (SNP) | VAF 83/192 reads (43%) | called by muse, mutect2, varscan2
- NAA38 | c.147C>G p.L49= (on ENST00000575771 / NM_001320925.2; = p.L97= on NM_032356.5) | Silent (SNP) | VAF 56/64 reads (88%) | catalogued as COSV54680248; called by muse, mutect2
- NLRP7 | c.1117C>T p.L373= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1437287875; called by muse, mutect2, varscan2
- OSBPL10 | c.42C>T p.S14= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs960682157; called by muse, mutect2
- PARG | c.300A>G p.E100= | Silent (SNP) | VAF 57/141 reads (40%) | called by muse, mutect2, varscan2
- RBL2 | c.147C>T p.F49= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs757366702; called by muse, mutect2, varscan2
- SLC7A10 | c.36G>C p.G12= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SNAPC3 | c.219G>A p.G73= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as rs750295441, COSV66459793; called by muse, mutect2, varscan2
- SYNGR3 | c.342C>G p.L114= | Silent (SNP) | VAF 61/67 reads (91%) | called by muse, mutect2, varscan2
- TAGAP | c.1788T>C p.Y596= | Silent (SNP) | VAF 90/175 reads (51%) | called by muse, mutect2, varscan2
- TCHHL1 | c.180G>A p.L60= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs1218184660; called by muse, mutect2, varscan2
- TMEM250 | c.174C>G p.L58= | Silent (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- ABHD14A | chr3:51973779 G>A | 5'Flank (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- ADD2 | c.*2165G>C | 3'UTR (SNP) | VAF 65/154 reads (42%) | called by muse, mutect2, varscan2
- AFAP1 | c.*4261G>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- AK7 | c.294+195G>C | Intron (SNP) | VAF 30/32 reads (94%) | called by muse, mutect2, varscan2
- APAF1 | c.*117C>T | 3'UTR (SNP) | VAF 64/68 reads (94%) | called by muse, mutect2, varscan2
- ATP2B4 | c.*1162G>C | 3'UTR (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- ATXN7 | c.*3107G>A | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- ATXN7 | c.*3813G>C | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- BCL11B | c.*1657del | 3'UTR (DEL) | VAF 22/28 reads (79%) | catalogued as rs1030424498; called by mutect2, varscan2
- BMP6 | c.*1028G>A | 3'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- BVES | c.*3781C>T | 3'UTR (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- C5orf22 | c.-87G>C | 5'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- CAND1 | c.*993G>C | 3'UTR (SNP) | VAF 52/54 reads (96%) | called by muse, mutect2, varscan2
- CCDC39 | chr3:180679714 G>C | 5'Flank (SNP) | VAF 63/108 reads (58%) | called by muse, mutect2, varscan2
- CCDC85C | c.*3014G>C | 3'UTR (SNP) | VAF 15/16 reads (94%) | catalogued as rs1455815668; called by muse, mutect2, varscan2
- CD300E | c.*2662C>G | 3'UTR (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- CDKN1B | c.-132C>T | 5'UTR (SNP) | VAF 45/99 reads (45%) | catalogued as rs928467438; called by muse, varscan2
- COG8 | chr16:69322786 C>T | 3'Flank (SNP) | VAF 16/25 reads (64%) | catalogued as rs1226590781; called by muse, mutect2, varscan2
- CRK | c.*2396C>T | 3'UTR (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- DCLK3 | c.*77_*87del | 3'UTR (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- DDC | c.945-80G>C | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- DDIT3 | c.-81+1238G>T | Intron (SNP) | VAF 15/77 reads (19%) | called by muse, varscan2
- DHX29 | c.-26G>A | 5'UTR (SNP) | VAF 63/122 reads (52%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*1923C>T | 3'UTR (SNP) | VAF 52/106 reads (49%) | catalogued as COSV101422623; called by muse, mutect2, varscan2
- DRAXIN | c.*2247G>A | 3'UTR (SNP) | VAF 11/14 reads (79%) | catalogued as rs1283457749; called by muse, mutect2, varscan2
- ELOVL2 | c.*2366C>G | 3'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- EPHA3 | c.*252C>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- EPPK1 | c.*250C>G | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- F11 | c.*255A>G | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- FAM205BP | n.3084G>A | RNA (SNP) | VAF 15/206 reads (7%) | called by muse, mutect2
- FAM83H | c.*381C>T | 3'UTR (SNP) | VAF 17/29 reads (59%) | catalogued as rs1415983824; called by muse, mutect2, varscan2
- FER | c.*1448C>T | 3'UTR (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- FJX1 | c.-113G>A | 5'UTR (SNP) | VAF 32/50 reads (64%) | called by muse, mutect2, varscan2
- FOXF1 | c.*856G>A | 3'UTR (SNP) | VAF 31/68 reads (46%) | catalogued as rs1007841960; called by muse, mutect2, varscan2
- FRMD5 | c.*1706G>A | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- GLB1L2 | c.-69G>A | 5'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2
- GLRX | c.208-97G>A | Intron (SNP) | VAF 85/141 reads (60%) | called by muse, mutect2, varscan2
- GPR149 | c.*70G>C | 3'UTR (SNP) | VAF 143/280 reads (51%) | called by muse, mutect2, varscan2
- HABP4 | c.-55C>T | 5'UTR (SNP) | VAF 36/57 reads (63%) | called by muse, mutect2
- HERC5 | c.*221C>G | 3'UTR (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- HHAT | c.1245+12C>T | Intron (SNP) | VAF 34/45 reads (76%) | catalogued as rs1341556041; called by muse, mutect2, varscan2
- HNRNPC | c.*63C>T | 3'UTR (SNP) | VAF 34/53 reads (64%) | called by muse, mutect2, varscan2
- HOXA13 | c.*2239A>G | 3'UTR (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*2761C>T | 3'UTR (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2
- IQCG | c.888+58G>A | Intron (SNP) | VAF 59/105 reads (56%) | called by muse, mutect2, varscan2
- IRGC | c.-39C>G | 5'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- ITGB2-AS1 | chr21:44933250 G>A | 3'Flank (SNP) | VAF 41/91 reads (45%) | catalogued as rs1163560244; called by muse, mutect2, varscan2
- IVNS1ABP | c.657+389G>T | Intron (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- KDM5B | c.*1388C>G | 3'UTR (SNP) | VAF 38/47 reads (81%) | called by muse, mutect2, varscan2
- LHX3 | c.*367C>T | 3'UTR (SNP) | VAF 76/145 reads (52%) | called by muse, mutect2, varscan2
- LIF | c.*1289G>A | 3'UTR (SNP) | VAF 102/190 reads (54%) | called by muse, mutect2, varscan2
- LIME1 | c.*133G>A | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- LPGAT1 | chr1:211746358 C>T | 3'Flank (SNP) | VAF 18/100 reads (18%) | called by muse, varscan2
- LRP1 | c.*742C>A | 3'UTR (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- LTBP3 | c.*191C>G | 3'UTR (SNP) | VAF 49/112 reads (44%) | called by mutect2, varscan2
- MAP2K1 | c.*541G>A | 3'UTR (SNP) | VAF 16/30 reads (53%) | catalogued as rs1411292187; called by muse, mutect2, varscan2
- MCTP2 | c.*874G>A | 3'UTR (SNP) | VAF 46/82 reads (56%) | catalogued as rs1398226492; called by muse, mutect2, varscan2
- MEIS1 | c.1024+553C>G | Intron (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- MLXIPL | c.2441-55G>A | Intron (SNP) | VAF 35/170 reads (21%) | catalogued as COSV100515421; called by muse, mutect2, varscan2
- MRPL53 | c.*22G>C | 3'UTR (SNP) | VAF 53/57 reads (93%) | called by muse, mutect2, varscan2
- MYH9 | c.*124C>T | 3'UTR (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- NAV3 | c.*1301G>A | 3'UTR (SNP) | VAF 50/55 reads (91%) | called by muse, mutect2, varscan2
- NEK7 | c.*2073G>A | 3'UTR (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- NEMP2 | c.*1708C>G | 3'UTR (SNP) | VAF 81/179 reads (45%) | called by muse, mutect2, varscan2
- NF2 | c.*3477C>G | 3'UTR (SNP) | VAF 74/156 reads (47%) | called by muse, mutect2, varscan2
- NOC2LP1 | n.2150C>T | RNA (SNP) | VAF 20/58 reads (34%) | catalogued as rs1279857133; called by muse, varscan2
- NTPCR | c.*54G>C | 3'UTR (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+4674C>T | Intron (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- OPCML | c.*4660G>A | 3'UTR (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- OPCML | c.*3492T>A | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- OR6B1 | chr7:144005062 C>G | 3'Flank (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- PDE10A | c.*124C>G | 3'UTR (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100606050; called by muse, mutect2, varscan2
- PHACTR2 | c.*4565G>A | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1719+1746G>A | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
- PICK1 | c.283-28C>T | Intron (SNP) | VAF 61/136 reads (45%) | catalogued as rs1238058898; called by muse, mutect2, varscan2
- PKN2 | c.*479G>A | 3'UTR (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- PLAA | c.*1176C>T | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, varscan2
- POU3F4 | c.*3G>A | 3'UTR (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- PPARD | c.*193C>T | 3'UTR (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- PPP1R12B | c.*4409G>C | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by mutect2, varscan2
- PPP2R5E | c.-26C>G | 5'UTR (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2
- PTCHD1 | c.*1898G>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- PYROXD1 | chr12:21437652 C>T | 5'Flank (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- RERE | c.*149C>G | 3'UTR (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.*566G>A | 3'UTR (SNP) | VAF 83/86 reads (97%) | called by muse, mutect2, varscan2
- RTN4RL2 | c.-15G>A | 5'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- RUNDC3B | c.-72G>C | 5'UTR (SNP) | VAF 6/93 reads (6%) | catalogued as rs1261481539, COSV55966364; called by muse, mutect2
- RYR2 | c.*579C>T | 3'UTR (SNP) | VAF 19/46 reads (41%) | catalogued as rs1360848746, COSV100771007; called by muse, varscan2
- SEMA3F | chr3:50155273 C>T | 5'Flank (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- SEPTIN3 | c.-206C>T | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- SETMAR | c.1020+447C>T | Intron (SNP) | VAF 59/135 reads (44%) | catalogued as rs1204026711; called by muse, mutect2
- SIK1 | c.*1632C>G | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- SLC9A6 | c.*1878G>A | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- SLC9B2 | c.*2+156G>A | Intron (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- SMIM27 | c.45+429G>T | Intron (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- SRGAP2 | c.*304G>C | 3'UTR (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- STRN | c.*2923C>G | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- TFF3 | c.-208G>A | 5'UTR (SNP) | VAF 13/287 reads (5%) | called by muse, mutect2
- THBS2 | c.*859G>A | 3'UTR (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- TMEM123 | c.*1801T>C | 3'UTR (SNP) | VAF 43/100 reads (43%) | catalogued as rs1003174529; called by muse, mutect2, varscan2
- TRAIP | c.*206G>A | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- TRAK1 | c.*621C>T | 3'UTR (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- TTC28 | c.*1093C>T | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1174C>T | 3'UTR (SNP) | VAF 93/187 reads (50%) | catalogued as rs1561802509; called by muse, mutect2, varscan2
- UNC79 | c.3754+1531G>T | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as COSV56380446, COSV99829494; called by muse, mutect2, varscan2
- USHBP1 | c.1047-23C>T | Intron (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- USP13 | c.-6G>A | 5'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- VKORC1L1 | c.*2494G>A | 3'UTR (SNP) | VAF 51/109 reads (47%) | catalogued as rs1272878184; called by muse, mutect2, varscan2
- WDR36 | c.*2446G>C | 3'UTR (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- ZDHHC9 | c.*890C>T | 3'UTR (SNP) | VAF 28/30 reads (93%) | called by muse, mutect2, varscan2
- ZNF280D | c.381+3020G>C | Intron (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- ZNF280D | c.-120C>T | 5'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- ZNF300P1 | n.1070_1084del | RNA (DEL) | VAF 12/35 reads (34%) | called by muse*, mutect2, varscan2*
- ZNF43 | c.*330G>C | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- ZNF516 | chr18:76496559 C>T | 5'Flank (SNP) | VAF 19/48 reads (40%) | catalogued as rs1327991849; called by muse, mutect2, varscan2
- ZNF529 | chr19:36573377 G>A | 5'Flank (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2
- ZNF660 | c.*2757C>G | 3'UTR (SNP) | VAF 76/141 reads (54%) | called by muse, mutect2, varscan2
- ZNF704 | c.*9758G>A | 3'UTR (SNP) | VAF 47/100 reads (47%) | catalogued as rs937118678; called by muse, mutect2, varscan2
